Somatic mutation profile of tumor specimen TCGA-66-2771-01A (aliquot TCGA-66-2771-01A-01D-0983-08) from TCGA case TCGA-66-2771, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIB; Age at diagnosis: 60.8 years (22,219 days).
Specimen TCGA-66-2771-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c752dd24-670b-473a-a12a-16756c90502a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-66-2771-11A (Solid Tissue Normal), aliquot TCGA-66-2771-11A-01D-0983-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1a2754f9-8aee-4625-b778-69af37b5eb36

The open-access MAF lists 249 somatic variants for this specimen: 183 protein-altering or splice-affecting, 60 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 156, Silent 60, Nonsense Mutation 15, Frame Shift Del 8, RNA 3, Intron 2, Translation Start Site 1, In Frame Del 1, Splice Site 1, 3'Flank 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MYH7 | c.3349G>T p.E1117* | Nonsense Mutation (SNP) | VAF 10/37 reads (27%) | catalogued as rs141735183; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- A2M | c.2345C>G p.S782C | Missense Mutation (SNP) | VAF 21/140 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.838); catalogued as COSV59393713; called by muse, mutect2, varscan2
- ACP1 | c.334G>C p.A112P | Missense Mutation (SNP) | VAF 19/56 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV55245889; called by muse, mutect2, varscan2
- ACTA1 | c.90G>T p.R30S | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.975); catalogued as COSV64204244; called by muse, mutect2, varscan2
- ACTA1 | c.89G>T p.R30M | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.984); catalogued as COSV100796813; called by muse, mutect2, varscan2
- ADGRL2 | c.2935G>C p.E979Q (on ENST00000370717 / NM_001366005.1; = p.E966Q on NM_012302.4) | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT tolerated (0.27); PolyPhen benign (0.005); catalogued as COSV54666568, COSV54666934, COSV54686553; called by muse, mutect2, varscan2
- AGO3 | c.1404G>C p.L468F | Missense Mutation (SNP) | VAF 7/112 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.189); catalogued as COSV55797923; called by muse, mutect2
- AKAP3 | c.1618G>T p.A540S | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.975); catalogued as COSV57421653; called by muse, varscan2
- ALPK2 | c.5255C>G p.S1752* | Nonsense Mutation (SNP) | VAF 6/54 reads (11%) | catalogued as rs1568077044, COSV100864870, COSV64498116; called by muse, mutect2, varscan2
- ANKLE2 | c.1597G>A p.E533K | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.873); catalogued as rs1468097077, COSV61710269, COSV61712105; called by muse, mutect2, varscan2
- APLNR | c.188C>T p.S63L | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT tolerated (0.2); PolyPhen benign (0.194); catalogued as COSV57244289; called by muse, mutect2, varscan2
- ARHGAP31 | c.3989C>T p.S1330F | Missense Mutation (SNP) | VAF 9/126 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.054); catalogued as COSV51799795; called by muse, mutect2
- ARHGEF40 | c.2434G>T p.D812Y | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.554); catalogued as COSV53885033; called by muse, mutect2, varscan2
- ASB17 | c.541A>C p.I181L | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT tolerated (0.15); PolyPhen benign (0.01); catalogued as COSV52410452; called by muse, mutect2, varscan2
- ATP10B | c.1388G>A p.R463Q | Missense Mutation (SNP) | VAF 18/63 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs368107402, COSV58779813; called by muse, mutect2, varscan2
- ATP6V0A2 | c.805C>G p.R269G | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.431); catalogued as COSV57752303, COSV57752869; called by muse, mutect2, varscan2
- B3GNT4 | c.865C>T p.R289W | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as COSV57336878; called by muse, mutect2, varscan2
- BMX | c.1778C>T p.S593L | Missense Mutation (SNP) | VAF 11/61 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59594197; called by muse, mutect2, varscan2
- C10orf90 | c.1252A>G p.K418E | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT deleterious (0.05); PolyPhen benign (0.359); catalogued as rs1320884873, COSV52965905; called by muse, mutect2, varscan2
- C1QTNF1 | c.639del p.N214Tfs*6 | Frame Shift Del (DEL) | VAF 37/99 reads (37%) | catalogued as COSV59260426; called by mutect2, pindel, varscan2
- C1R | c.2089G>T p.G697C (on ENST00000536053 / NM_001354346.2; = p.G683C on NM_001733.7) | Missense Mutation (SNP) | VAF 13/72 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV73383067; called by muse, mutect2, varscan2
- CAMTA1 | c.2567C>T p.S856L | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.003); catalogued as rs1218936927, COSV57932101; called by muse, mutect2, varscan2
- CBWD2 | c.20C>G p.S7C | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0); catalogued as COSV52077010; called by muse, mutect2, varscan2
- CCDC86 | c.395G>A p.G132E | Missense Mutation (SNP) | VAF 13/76 reads (17%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV57126504; called by muse, mutect2, varscan2
- CD5L | c.292G>T p.G98* | Nonsense Mutation (SNP) | VAF 61/176 reads (35%) | catalogued as COSV63823390; called by muse, mutect2, varscan2
- CDCA2 | c.71C>G p.S24C | Missense Mutation (SNP) | VAF 30/159 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.723); catalogued as COSV55341932; called by muse, varscan2
- CDH8 | c.2275C>A p.L759I | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT tolerated (0.11); PolyPhen probably damaging (1); catalogued as COSV100184600; called by muse, mutect2
- CEP350 | c.842A>G p.K281R | Missense Mutation (SNP) | VAF 34/138 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV62486271; called by muse, mutect2, varscan2
- CFAP221 | c.1462G>T p.D488Y | Missense Mutation (SNP) | VAF 5/45 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.742); catalogued as COSV54664163; called by muse, mutect2, varscan2
- CHD1 | c.2059C>A p.H687N | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV52345481; called by muse, mutect2, varscan2
- CLPTM1L | c.394A>G p.T132A | Missense Mutation (SNP) | VAF 13/86 reads (15%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.525); catalogued as COSV57993372; called by muse, mutect2, varscan2
- CLSPN | c.3980C>T p.S1327L | Missense Mutation (SNP) | VAF 10/83 reads (12%) | SIFT tolerated (0.15); PolyPhen benign (0.001); catalogued as COSV52058024; called by muse, mutect2, varscan2
- CNOT3 | c.2127C>G p.H709Q | Missense Mutation (SNP) | VAF 7/108 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV55369297; called by muse, mutect2
- COL11A2 | c.798G>T p.Q266H | Missense Mutation (SNP) | VAF 23/74 reads (31%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.948); catalogued as COSV59503654; called by muse, mutect2, varscan2
- COL19A1 | c.2176G>T p.A726S | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT tolerated (0.07); PolyPhen benign (0.012); catalogued as rs1277449817, COSV59591187; called by muse, mutect2, varscan2
- COL24A1 | c.1429G>T p.D477Y | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as COSV65309850; called by muse, mutect2, varscan2
- COL6A3 | c.7797del p.F2599Lfs*26 | Frame Shift Del (DEL) | VAF 18/126 reads (14%) | catalogued as COSV55088421; called by mutect2, varscan2
- COMMD1 | c.433A>G p.I145V | Missense Mutation (SNP) | VAF 20/78 reads (26%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV61281633; called by muse, mutect2, varscan2
- CPSF2 | c.1523A>G p.D508G | Missense Mutation (SNP) | VAF 16/99 reads (16%) | SIFT tolerated (0.12); PolyPhen benign (0.001); catalogued as COSV54101240; called by muse, mutect2, varscan2
- CSDE1 | c.1455A>G p.I485M (on ENST00000358528 / NM_001007553.3; = p.I454M on NM_007158.6) | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT tolerated (0.12); PolyPhen benign (0.025); catalogued as rs376861013; called by muse, mutect2, varscan2
- CSMD3 | c.10709T>C p.M3570T (on ENST00000297405 / NM_001363185.1; = p.M3401T on NM_052900.3) | Missense Mutation (SNP) | VAF 17/76 reads (22%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as COSV52345872; called by mutect2, varscan2
- CUBN | c.9543G>T p.K3181N | Missense Mutation (SNP) | VAF 23/48 reads (48%) | SIFT tolerated (0.36); PolyPhen benign (0.034); catalogued as COSV64729362; called by muse, mutect2, varscan2
- CYP11B2 | c.700A>C p.T234P | Missense Mutation (SNP) | VAF 11/23 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59998265; called by muse, mutect2, varscan2
- DCAF12L1 | c.660del p.W220Cfs*93 | Frame Shift Del (DEL) | VAF 8/18 reads (44%) | catalogued as COSV64421817, COSV64421896; called by mutect2, varscan2
- DCSTAMP | c.254T>C p.V85A | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as COSV52580631; called by muse, mutect2, varscan2
- DDR2 | c.511G>T p.D171Y | Missense Mutation (SNP) | VAF 12/70 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV63370699, COSV63375038; called by muse, mutect2, varscan2
- DPP10 | c.46T>A p.S16T | Missense Mutation (SNP) | VAF 11/61 reads (18%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as COSV69789404; called by muse, mutect2, varscan2
- DPY19L3 | c.1888T>A p.F630I | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT tolerated (0.11); PolyPhen benign (0.011); catalogued as COSV60480868; called by muse, mutect2, varscan2
- DYNC1H1 | c.6167C>T p.S2056L | Missense Mutation (SNP) | VAF 16/100 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64134991; called by mutect2, varscan2
- EDAR | c.1327C>T p.Q443* | Nonsense Mutation (SNP) | VAF 6/15 reads (40%) | catalogued as COSV51508684; called by muse, mutect2, varscan2
- EEF1AKMT4 | c.503G>C p.G168A | Missense Mutation (SNP) | VAF 10/188 reads (5%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as COSV99955636; called by muse, mutect2
- EGF | c.631G>C p.D211H | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.735); catalogued as COSV54485841, COSV99490313; called by muse, mutect2, varscan2
- ESR1 | c.587A>G p.H196R | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52804109; called by muse, mutect2, varscan2
- ESRRG | c.277G>T p.G93C | Missense Mutation (SNP) | VAF 18/86 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.161); catalogued as COSV63184685; called by muse, mutect2, varscan2
- EVA1B | c.37A>C p.N13H | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.347); catalogued as COSV54635755; called by muse, mutect2, varscan2
- FAM110B | c.172A>T p.K58* | Nonsense Mutation (SNP) | VAF 9/31 reads (29%) | catalogued as COSV64068660; called by muse, mutect2, varscan2
- FAT4 | c.5461C>T p.Q1821* | Nonsense Mutation (SNP) | VAF 8/102 reads (8%) | catalogued as COSV58713033; called by muse, mutect2
- FBN3 | c.3645G>A p.M1215I | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV54475447; called by muse, mutect2, varscan2
- FCER1G | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 22/88 reads (25%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.775); catalogued as COSV57156355; called by muse, mutect2, varscan2
- FILIP1 | c.2555T>C p.V852A | Missense Mutation (SNP) | VAF 22/88 reads (25%) | SIFT tolerated (0.15); PolyPhen benign (0.007); catalogued as COSV52742649; called by muse, mutect2, varscan2
- FOXA1 | c.472G>A p.D158N | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.784); catalogued as rs771653601, COSV51646911, COSV51648723; called by muse, mutect2, varscan2
- FRAS1 | c.6328G>A p.D2110N | Missense Mutation (SNP) | VAF 6/84 reads (7%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.717); catalogued as rs1297235682; called by muse, mutect2
- GDAP1 | c.683A>G p.E228G | Missense Mutation (SNP) | VAF 18/90 reads (20%) | SIFT tolerated (0.27); PolyPhen benign (0.039); catalogued as COSV55187564; called by muse, mutect2, varscan2
- GIMAP7 | c.364T>A p.S122T | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT tolerated (0.15); PolyPhen benign (0.131); catalogued as COSV57961037; called by muse, mutect2
- GK2 | c.822A>T p.Q274H | Missense Mutation (SNP) | VAF 17/96 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.676); catalogued as COSV62628671; called by muse, mutect2, varscan2
- GLG1 | c.2711T>G p.L904W | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52675707; called by mutect2, varscan2
- GNAI1 | c.928C>G p.L310V | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.338); catalogued as COSV63525660; called by muse, mutect2, varscan2
- GPD2 | c.2044A>C p.N682H | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as COSV60097796; called by muse, mutect2, varscan2
- GRIN2A | c.2563G>C p.D855H | Missense Mutation (SNP) | VAF 17/106 reads (16%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.862); catalogued as COSV100410936, COSV58024134, COSV58059538; called by muse, mutect2, varscan2
- GUSB | c.1750G>T p.E584* | Nonsense Mutation (SNP) | VAF 28/147 reads (19%) | catalogued as COSV59224379; called by muse, mutect2, varscan2
- HACE1 | c.1684A>C p.I562L | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as COSV53508872; called by muse, mutect2, varscan2
- HEPH | c.1675G>A p.V559M (on ENST00000343002; = p.V292M on NM_014799.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/11 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1449346234, COSV57973945; called by mutect2, varscan2
- HMCN1 | c.6527C>T p.A2176V | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV54948555; called by muse, mutect2, varscan2
- IGF1 | c.426G>C p.K142N | Missense Mutation (SNP) | VAF 11/131 reads (8%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.987); catalogued as COSV61032085, COSV61035248; called by muse, mutect2
- IKBKE | c.1721A>G p.H574R | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1553390150, COSV65623929; called by muse, mutect2, varscan2
- INSC | c.1103G>A p.S368N | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV65413696; called by muse, mutect2, varscan2
- JAK2 | c.1298A>G p.N433S | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.13); catalogued as COSV67685993; called by muse, mutect2
- KIF4A | c.1243C>T p.Q415* | Nonsense Mutation (SNP) | VAF 5/73 reads (7%) | catalogued as COSV65545979, COSV65546409; called by muse, mutect2
- KLHL23 | c.1206G>C p.M402I | Missense Mutation (SNP) | VAF 24/95 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.952); catalogued as COSV55870227; called by muse, mutect2, varscan2
- KLK8 | c.322T>A p.C108S | Missense Mutation (SNP) | VAF 16/82 reads (20%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as COSV99144130; called by mutect2, varscan2
- KLKB1 | c.604C>T p.H202Y | Missense Mutation (SNP) | VAF 18/85 reads (21%) | SIFT tolerated (0.22); PolyPhen benign (0.373); catalogued as COSV53000172; called by muse, mutect2, varscan2
- KRT2 | c.1882G>C p.E628Q | Missense Mutation (SNP) | VAF 6/102 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); catalogued as COSV59013096; called by muse, mutect2
- LAMA3 | c.7478A>T p.Q2493L (on ENST00000313654 / NM_198129.4; = p.Q884L on NM_000227.6) | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV52545019; called by muse, mutect2
- LAMB1 | c.4258G>A p.E1420K | Missense Mutation (SNP) | VAF 12/81 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.047); catalogued as rs564358099, COSV55967593; called by muse, mutect2, varscan2
- LAMB4 | c.1168T>A p.Y390N | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.265); catalogued as COSV52733117; called by mutect2, varscan2
- LRP1B | c.11566C>T p.H3856Y | Missense Mutation (SNP) | VAF 13/70 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.266); catalogued as COSV67283728; called by muse, mutect2, varscan2
- LRP1B | c.11449T>C p.Y3817H | Missense Mutation (SNP) | VAF 3/23 reads (13%) | SIFT tolerated (0.5); PolyPhen possibly damaging (0.459); catalogued as COSV67283730; called by muse, mutect2
- LRP1B | c.7552T>A p.C2518S | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV67283731; called by muse, mutect2, varscan2
- LRRC7 | c.3389C>T p.S1130F (on ENST00000651989 / NM_001370785.2; = p.S1097F on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 19/63 reads (30%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.609); catalogued as COSV50653011; called by muse, mutect2, varscan2
- LRRC7 | c.4156G>T p.V1386L (on ENST00000651989 / NM_001370785.2; = p.V1306L on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 14/64 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as COSV50653090; called by muse, mutect2, varscan2
- MARCHF2 | c.370G>A p.E124K | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as COSV53107085; called by muse, mutect2, varscan2
- MGA | c.6551G>T p.R2184M (on ENST00000219905 / NM_001164273.1; = p.R1975M on NM_001080541.2) | Missense Mutation (SNP) | VAF 25/109 reads (23%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.087); catalogued as COSV54964681; called by muse, mutect2, varscan2
- MMP10 | c.532C>A p.H178N | Missense Mutation (SNP) | VAF 14/67 reads (21%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as rs1490265717, COSV54246020; called by muse, mutect2, varscan2
- MRAP2 | c.170T>C p.V57A | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV57635429; called by muse, mutect2, varscan2
- MRPL18 | c.176T>C p.L59S | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV58460708; called by muse, mutect2, varscan2
- MTPAP | c.1736G>C p.S579T | Missense Mutation (SNP) | VAF 39/111 reads (35%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.014); catalogued as COSV53933333, COSV53936748; called by muse, mutect2, varscan2
- MUC16 | c.3349G>C p.E1117Q | Missense Mutation (SNP) | VAF 5/82 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.25); catalogued as COSV67451931, COSV67491091, COSV67500653; called by muse, mutect2
- NCBP1 | c.2323G>C p.D775H | Missense Mutation (SNP) | VAF 14/71 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV64305887; called by muse, mutect2, varscan2
- NEK11 | c.688C>G p.H230D | Missense Mutation (SNP) | VAF 20/108 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV63579269, COSV63584287; called by muse, varscan2
- NIFK | c.826G>C p.E276Q | Missense Mutation (SNP) | VAF 6/75 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.074); catalogued as COSV53535987; called by muse, mutect2
- NLRP4 | c.982G>T p.V328L | Missense Mutation (SNP) | VAF 10/63 reads (16%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.584); catalogued as rs371603998, COSV100017399; called by muse, mutect2, varscan2
- NRIP1 | c.2881A>G p.K961E | Missense Mutation (SNP) | VAF 13/60 reads (22%) | SIFT tolerated (0.2); PolyPhen benign (0.273); catalogued as rs757429406, COSV59660252; called by muse, mutect2, varscan2
- NRXN1 | c.3856G>A p.A1286T | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.01); catalogued as COSV60527468; called by muse, mutect2
- NXPE1 | c.1325T>G p.F442C (on ENST00000424269; = p.F300C on NM_152315.5) | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52634088; called by muse, mutect2, varscan2
- OPLAH | c.2491G>C p.D831H | Missense Mutation (SNP) | VAF 3/16 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV70679510; called by mutect2, varscan2
- OPRM1 | c.82C>T p.P28S | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated (0.79); PolyPhen benign (0); catalogued as COSV57687064; called by muse, mutect2
- OR13C9 | c.476A>G p.Q159R | Missense Mutation (SNP) | VAF 24/74 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV52243991, COSV99403393; called by muse, mutect2, varscan2
- OR2G6 | c.709G>A p.A237T | Missense Mutation (SNP) | VAF 11/63 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.914); catalogued as COSV58576124; called by muse, mutect2, varscan2
- OR2T4 | c.818G>T p.C273F | Missense Mutation (SNP) | VAF 18/121 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV63545275; called by muse, varscan2
- OR4Q3 | c.677C>T p.S226F | Missense Mutation (SNP) | VAF 11/79 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59177587, COSV59180701; called by muse, mutect2, varscan2
- OSBPL1A | c.376A>T p.I126F | Missense Mutation (SNP) | VAF 7/53 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.289); catalogued as COSV60205371; called by muse, mutect2, varscan2
- OXNAD1 | c.286C>T p.Q96* | Nonsense Mutation (SNP) | VAF 12/43 reads (28%) | catalogued as COSV53269350; called by muse, mutect2, varscan2
- PAX5 | c.1057T>A p.S353T | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV63910810, COSV63914389; called by muse, mutect2, varscan2
- PCDHA6 | c.1154T>C p.V385A | Missense Mutation (SNP) | VAF 38/146 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); catalogued as COSV67092133; called by muse, varscan2
- PCSK1 | c.2176G>A p.D726N | Missense Mutation (SNP) | VAF 30/112 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV60737923; called by muse, varscan2
- PGBD2 | c.859G>T p.G287W | Missense Mutation (SNP) | VAF 22/96 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100252297, COSV61400378; called by muse, mutect2, varscan2
- PIK3CG | c.571C>A p.R191S | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.646); catalogued as COSV63247222, COSV63247355; called by muse, mutect2, varscan2
- PLD5 | c.1355-2A>T p.X452_splice (on ENST00000442594; = p.X390_splice on NM_001195811.1 and 1 other RefSeq transcript) | Splice Site (SNP) | VAF 15/69 reads (22%) | catalogued as COSV100143565; called by muse, mutect2, varscan2
- POLQ | c.3046G>T p.V1016F | Missense Mutation (SNP) | VAF 12/94 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.226); catalogued as COSV51758911; called by muse, mutect2, varscan2
- PSG2 | c.95C>T p.T32I | Missense Mutation (SNP) | VAF 14/138 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.248); catalogued as COSV68885437; called by muse, mutect2, varscan2
- RABL6 | c.494T>G p.V165G | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100273865; called by mutect2, varscan2
- RO60 | c.541G>C p.D181H | Missense Mutation (SNP) | VAF 11/78 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66475305; called by muse, mutect2, varscan2
- RP1 | c.5704C>T p.Q1902* | Nonsense Mutation (SNP) | VAF 6/62 reads (10%) | catalogued as COSV55128838; called by muse, mutect2, varscan2
- RPL10L | c.325G>C p.D109H | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.061); catalogued as COSV53561973; called by muse, mutect2, varscan2
- RRP15 | c.642G>T p.L214F | Missense Mutation (SNP) | VAF 16/55 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65117600, COSV65118813; called by muse, mutect2, varscan2
- RTN4IP1 | c.667C>G p.Q223E | Missense Mutation (SNP) | VAF 14/64 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV63152219; called by muse, mutect2, varscan2
- SALL3 | c.2579C>G p.T860S | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT tolerated (0.91); PolyPhen benign (0); catalogued as COSV73306718; called by muse, mutect2, varscan2
- SAP130 | c.332A>T p.H111L | Missense Mutation (SNP) | VAF 22/71 reads (31%) | SIFT tolerated, low confidence (0.34); PolyPhen possibly damaging (0.677); catalogued as COSV52104074; called by muse, mutect2, varscan2
- SENP5 | c.794G>A p.R265Q | Missense Mutation (SNP) | VAF 13/63 reads (21%) | SIFT tolerated (0.21); PolyPhen benign (0.001); catalogued as rs766110657, COSV60207241, COSV60207810; called by muse, mutect2, varscan2
- SERPINC1 | c.1244C>A p.A415D | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV62930915; called by muse, mutect2
- SFI1 | c.295T>C p.W99R | Missense Mutation (SNP) | VAF 17/59 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV66293471; called by muse, mutect2, varscan2
- SI | c.2251G>T p.D751Y | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.826); catalogued as COSV52305036; called by muse, mutect2, varscan2
- SIGLEC6 | c.380G>A p.W127* | Nonsense Mutation (SNP) | VAF 16/94 reads (17%) | catalogued as COSV58432648; called by muse, mutect2, varscan2
- SLC35F1 | c.1017T>A p.Y339* | Nonsense Mutation (SNP) | VAF 15/91 reads (16%) | catalogued as COSV64511211; called by muse, mutect2, varscan2
- SMC1B | c.2075T>A p.L692H | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.754); catalogued as COSV62533968; called by muse, mutect2, varscan2
- SMR3A | c.337C>G p.P113A | Missense Mutation (SNP) | VAF 13/70 reads (19%) | SIFT tolerated, low confidence (0.68); PolyPhen possibly damaging (0.74); catalogued as COSV56951625; called by muse, mutect2, varscan2
- SORCS3 | c.2863A>G p.T955A | Missense Mutation (SNP) | VAF 49/135 reads (36%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.881); catalogued as rs1227860243, COSV63799401; called by muse, mutect2, varscan2
- SPATA6 | c.1198G>T p.E400* | Nonsense Mutation (SNP) | VAF 19/80 reads (24%) | catalogued as COSV100893066, COSV64057418; called by muse, mutect2, varscan2
- SRFBP1 | c.859A>G p.I287V | Missense Mutation (SNP) | VAF 20/66 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.055); catalogued as rs1241267153, COSV59585326; called by muse, mutect2, varscan2
- STPG2 | c.7G>A p.D3N | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.769); catalogued as COSV54799212, COSV54825068; called by muse, mutect2
- SYNE1 | c.6808A>G p.T2270A (on ENST00000367255 / NM_182961.4; = p.T2277A on NM_033071.3) | Missense Mutation (SNP) | VAF 11/69 reads (16%) | SIFT tolerated (0.29); PolyPhen benign (0.118); catalogued as COSV55076979; called by muse, mutect2, varscan2
- TADA2B | c.877C>T p.R293W | Missense Mutation (SNP) | VAF 4/37 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV53826835; called by mutect2, varscan2
- TBX19 | c.392T>G p.F131C | Missense Mutation (SNP) | VAF 33/158 reads (21%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); catalogued as COSV63198624; called by muse, mutect2, varscan2
- TEK | c.2441C>A p.T814K | Missense Mutation (SNP) | VAF 16/28 reads (57%) | SIFT deleterious (0); PolyPhen benign (0.045); catalogued as COSV66236090; called by muse, mutect2, varscan2
- TG | c.7162G>C p.G2388R | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55077203, COSV55097415; called by muse, mutect2, varscan2
- TMEM200C | c.209C>T p.A70V | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV101274841, COSV67310135; called by muse, mutect2, varscan2
- TNFAIP3 | c.2333A>G p.Y778C | Missense Mutation (SNP) | VAF 28/138 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV52803096; called by muse, mutect2
- TNR | c.1331G>T p.G444V | Missense Mutation (SNP) | VAF 42/260 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV54918294; called by muse, mutect2, varscan2
- TOGARAM2 | c.1121G>T p.R374M | Missense Mutation (SNP) | VAF 11/100 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.956); catalogued as COSV65424329; called by muse, mutect2, varscan2
- TRPA1 | c.2165A>G p.N722S | Missense Mutation (SNP) | VAF 9/61 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1416445017, COSV51576244; called by muse, mutect2
- TRPA1 | c.1863T>A p.C621* | Nonsense Mutation (SNP) | VAF 7/43 reads (16%) | catalogued as COSV51576264; called by muse, mutect2, varscan2
- TTN | c.100055C>T p.T33352M (on ENST00000591111; = p.T25928M on NM_003319.4) | Missense Mutation (SNP) | VAF 13/64 reads (20%) | PolyPhen benign (0.003); catalogued as rs368945564, COSV60067083; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- TTN | c.6499C>A p.L2167I (on ENST00000591111; = p.L2121I on NM_003319.4) | Missense Mutation (SNP) | VAF 10/65 reads (15%) | PolyPhen probably damaging (0.996); catalogued as COSV60404187; called by muse, mutect2, varscan2
- UBB | c.140G>T p.G47V | Missense Mutation (SNP) | VAF 11/89 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV56219904; called by muse, mutect2, varscan2
- UHMK1 | c.251A>T p.Q84L | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.091); catalogued as COSV56421658; called by muse, mutect2, varscan2
- UNC13C | c.4736G>C p.R1579P | Missense Mutation (SNP) | VAF 13/77 reads (17%) | SIFT tolerated, low confidence (0.73); PolyPhen possibly damaging (0.737); catalogued as COSV52865506, COSV52932269; called by muse, mutect2, varscan2
- USP48 | c.2031G>T p.Q677H | Missense Mutation (SNP) | VAF 23/101 reads (23%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as COSV57615612; called by muse, mutect2, varscan2
- UTP20 | c.427G>C p.E143Q | Missense Mutation (SNP) | VAF 7/136 reads (5%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.849); catalogued as COSV55386693; called by muse, mutect2
- VN1R1 | c.424C>A p.L142I | Missense Mutation (SNP) | VAF 10/69 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV58091842; called by muse, mutect2, varscan2
- ZCCHC13 | c.395G>A p.R132Q | Missense Mutation (SNP) | VAF 18/37 reads (49%) | SIFT deleterious (0.01); PolyPhen benign (0.439); catalogued as COSV59866749; called by muse, mutect2, varscan2
- ZEB2 | c.808C>A p.H270N | Missense Mutation (SNP) | VAF 10/78 reads (13%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.773); catalogued as COSV57968003; called by muse, mutect2
- ZFHX3 | c.10385A>G p.Q3462R | Missense Mutation (SNP) | VAF 16/72 reads (22%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.447); catalogued as rs1397156550, COSV51739753; called by muse, mutect2, varscan2
- ZFHX4 | c.3547G>T p.V1183L | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT tolerated (0.79); PolyPhen benign (0.009); catalogued as COSV51500987; called by muse, mutect2, varscan2
- ZFX | c.377C>A p.S126* | Nonsense Mutation (SNP) | VAF 17/111 reads (15%) | catalogued as COSV58450301; called by muse, mutect2, varscan2
- ZHX2 | c.198G>T p.M66I | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as COSV100074080; called by muse, mutect2, varscan2
- ZMYM1 | c.1798G>A p.E600K | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.652); catalogued as COSV63254167; called by muse, mutect2, varscan2
- ZNF214 | c.1387G>T p.V463F | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.765); catalogued as COSV53484024; called by muse, mutect2, varscan2
- ZNF761 | c.1319G>C p.C440S | Missense Mutation (SNP) | VAF 26/118 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61889658; called by muse, mutect2, varscan2
- ZNF777 | c.1793T>A p.V598E | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT tolerated (0.13); PolyPhen benign (0.143); catalogued as COSV56100685, COSV99925255; called by muse, mutect2, varscan2
- ZNF804B | c.1372C>A p.P458T | Missense Mutation (SNP) | VAF 15/80 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60861123; called by muse, mutect2, varscan2
- ZNF813 | c.1453C>G p.H485D | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV101124921, COSV67178370; called by muse, mutect2, varscan2
- ZSWIM5 | c.3181A>C p.I1061L | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT tolerated (0.13); PolyPhen benign (0.328); catalogued as COSV55800401, COSV55802233; called by muse, mutect2, varscan2
- CAPN15 | c.2970_2976del p.E990Dfs*41 | Frame Shift Del (DEL) | VAF 6/36 reads (17%) | called by mutect2, pindel, varscan2
- EXO1 | c.1823_1825del p.C608del | In Frame Del (DEL) | VAF 23/96 reads (24%) | called by pindel, varscan2
- FCGBP | c.11446G>T p.A3816S | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.229); called by muse, mutect2, varscan2
- FOSL2 | c.590_594del p.E197Afs*60 | Frame Shift Del (DEL) | VAF 17/50 reads (34%) | called by mutect2, pindel, varscan2
- IGHV4-28 | c.29T>A p.L10Q | Missense Mutation (SNP) | VAF 6/61 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- LATS1 | c.442_449delinsT p.R148* | Frame Shift Del (DEL) | VAF 9/51 reads (18%) | called by pindel, varscan2*
- RPL23 | c.227-4_227-3del | Splice Region (DEL) | VAF 5/48 reads (10%) | called by pindel, varscan2
- SLC24A3 | c.775G>T p.A259S | Missense Mutation (SNP) | VAF 14/82 reads (17%) | SIFT tolerated (0.84); PolyPhen benign (0.003); called by mutect2, varscan2
- TP53 | c.708_727del p.M237Gfs*20 | Frame Shift Del (DEL) | VAF 5/43 reads (12%) | called by mutect2, pindel
- TRGV2 | c.232G>C p.E78Q | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT tolerated (0.11); PolyPhen benign (0.318); called by muse, mutect2, varscan2
- UNC5D | c.2123del p.L708* | Frame Shift Del (DEL) | VAF 18/103 reads (17%) | called by mutect2, varscan2
- ACSM5 | c.33G>A p.Q11= | Silent (SNP) | VAF 8/30 reads (27%) | catalogued as COSV59375476; called by mutect2, varscan2
- ADCY8 | c.2925T>A p.S975= | Silent (SNP) | VAF 12/65 reads (18%) | catalogued as COSV53932139; called by muse, mutect2, varscan2
- AHNAK2 | c.9939C>T p.F3313= | Silent (SNP) | VAF 18/435 reads (4%) | catalogued as COSV60933694; called by muse, mutect2
- AKAP3 | c.1617G>T p.L539= | Silent (SNP) | VAF 6/37 reads (16%) | catalogued as COSV57421668; called by muse, varscan2
- ALDH3B2 | c.606C>G p.G202= | Silent (SNP) | VAF 10/49 reads (20%) | catalogued as COSV100824162; called by mutect2, varscan2
- ANGEL2 | c.333C>T p.Y111= | Silent (SNP) | VAF 24/100 reads (24%) | catalogued as rs760701370, COSV64738549; called by muse, mutect2, varscan2
- ASPG | c.270C>T p.I90= | Silent (SNP) | VAF 24/118 reads (20%) | catalogued as rs374153867; called by muse, mutect2, varscan2
- ATR | c.7206A>T p.T2402= | Silent (SNP) | VAF 11/36 reads (31%) | catalogued as COSV63393725; called by muse, mutect2, varscan2
- BAX | c.189C>G p.L63= | Silent (SNP) | VAF 19/77 reads (25%) | catalogued as COSV99509330; called by mutect2, varscan2
- BMT2 | c.489A>C p.S163= | Silent (SNP) | VAF 19/68 reads (28%) | catalogued as COSV51778563, COSV51781753; called by muse, mutect2, varscan2
- CCDC93 | c.948C>G p.R316= | Silent (SNP) | VAF 7/39 reads (18%) | catalogued as COSV60124829; called by muse, mutect2, varscan2
- CDH26 | c.147A>T p.L49= | Silent (SNP) | VAF 30/117 reads (26%) | catalogued as COSV54856956; called by muse, varscan2
- CNGB3 | c.768G>A p.A256= | Silent (SNP) | VAF 8/53 reads (15%) | catalogued as rs767128005, COSV60689772; ClinVar: uncertain significance; called by mutect2, varscan2
- CNTNAP4 | c.2397C>A p.T799= | Silent (SNP) | VAF 22/114 reads (19%) | catalogued as COSV100273752; called by muse, mutect2, varscan2
- CNTNAP5 | c.2814G>A p.Q938= | Silent (SNP) | VAF 17/93 reads (18%) | catalogued as rs1399512654, COSV70494450; called by muse, mutect2, varscan2
- COASY | c.1518C>T p.L506= | Silent (SNP) | VAF 4/37 reads (11%) | catalogued as COSV55900668; called by mutect2, varscan2
- DEF8 | c.42G>A p.A14= | Silent (SNP) | VAF 13/65 reads (20%) | catalogued as rs1318074496, COSV51917755; called by mutect2, varscan2
- DEPTOR | c.219G>A p.L73= | Silent (SNP) | VAF 8/88 reads (9%) | catalogued as COSV53819186, COSV99639702; called by muse, mutect2
- DPP4 | c.27G>T p.L9= | Silent (SNP) | VAF 12/44 reads (27%) | catalogued as COSV62110600; called by muse, mutect2, varscan2
- E4F1 | c.519C>G p.L173= | Silent (SNP) | VAF 10/40 reads (25%) | catalogued as rs149258624, COSV57041764; called by mutect2, varscan2
- EFEMP1 | c.1263C>T p.N421= | Silent (SNP) | VAF 8/82 reads (10%) | catalogued as COSV62618264; called by muse, mutect2
- EGLN3 | c.402C>G p.R134= | Silent (SNP) | VAF 17/66 reads (26%) | catalogued as COSV51656532; called by muse, mutect2, varscan2
- ELMO1 | c.1263C>A p.T421= | Silent (SNP) | VAF 12/59 reads (20%) | catalogued as COSV60329104; called by muse, varscan2
- FHL5 | c.660C>T p.N220= | Silent (SNP) | VAF 15/65 reads (23%) | catalogued as COSV58741244; called by muse, mutect2, varscan2
- FTSJ1 | c.615C>T p.F205= | Silent (SNP) | VAF 6/11 reads (55%) | catalogued as rs1413840474, COSV50026542; called by muse, mutect2, varscan2
- GIMAP4 | c.819A>G p.E273= | Silent (SNP) | VAF 8/56 reads (14%) | catalogued as COSV55435034; called by muse, mutect2, varscan2
- GNB3 | c.132G>A p.Q44= | Silent (SNP) | VAF 9/34 reads (26%) | catalogued as rs1187778854, COSV51837044; called by muse, mutect2, varscan2
- GRIA1 | c.1326G>C p.L442= | Silent (SNP) | VAF 15/62 reads (24%) | catalogued as COSV99602900; called by muse, mutect2, varscan2
- H1-4 | c.528G>A p.A176= | Silent (SNP) | VAF 8/15 reads (53%) | catalogued as rs767476021, COSV56800683, COSV56801015; called by muse, mutect2, varscan2
- HEMK1 | c.786G>T p.A262= | Silent (SNP) | VAF 10/32 reads (31%) | catalogued as COSV51752238; called by muse, mutect2, varscan2
- INO80 | c.3703C>T p.L1235= | Silent (SNP) | VAF 12/263 reads (5%) | catalogued as COSV62743311; called by muse, mutect2
- LAMB4 | c.1167C>T p.P389= | Silent (SNP) | VAF 6/39 reads (15%) | catalogued as COSV52728102, COSV52733135; called by muse, mutect2, varscan2
- LRIT3 | c.1668A>T p.P556= | Silent (SNP) | VAF 8/55 reads (15%) | catalogued as COSV59988123; called by muse, mutect2, varscan2
- LRP5 | c.3129G>A p.E1043= | Silent (SNP) | VAF 13/63 reads (21%) | catalogued as COSV53724884; called by muse, varscan2
- MAGEC1 | c.2895G>A p.L965= | Silent (SNP) | VAF 8/102 reads (8%) | catalogued as COSV53582835; called by muse, mutect2
- NDUFB5 | c.318C>T p.V106= | Silent (SNP) | VAF 20/44 reads (45%) | catalogued as COSV52022022; called by muse, mutect2, varscan2
- NEU2 | c.933C>G p.L311= | Silent (SNP) | VAF 4/39 reads (10%) | catalogued as COSV52094352; called by mutect2, varscan2
- NFIB | c.168A>T p.A56= | Silent (SNP) | VAF 10/42 reads (24%) | catalogued as rs1341436007, COSV66621505; called by muse, mutect2, varscan2
- NLRP3 | c.2454G>T p.V818= | Silent (SNP) | VAF 12/73 reads (16%) | catalogued as COSV100276818; called by muse, mutect2, varscan2
- OPN1LW | c.357C>T p.F119= | Silent (SNP) | VAF 9/57 reads (16%) | catalogued as rs782670567, COSV100886842, COSV64064294; called by muse, mutect2, varscan2
- OR8A1 | c.174C>G p.P58= | Silent (SNP) | VAF 11/81 reads (14%) | catalogued as rs1378338620, COSV52510714; called by muse, mutect2, varscan2
- PCDHA6 | c.1434T>C p.S478= | Silent (SNP) | VAF 10/45 reads (22%) | catalogued as COSV65348273; called by muse, mutect2, varscan2
- POFUT2 | c.609G>C p.A203= | Silent (SNP) | VAF 9/28 reads (32%) | catalogued as COSV100499112, COSV57961745; called by muse, mutect2, varscan2
- PPP1R9B | c.2319G>A p.L773= | Silent (SNP) | VAF 5/18 reads (28%) | catalogued as rs1252460612, COSV57542630; called by muse, mutect2
- RABGEF1 | c.900G>A p.K300= (on ENST00000439720 / NM_001287061.2; = p.K287= on NM_014504.3 and 29 other RefSeq transcripts) | Silent (SNP) | VAF 18/57 reads (32%) | catalogued as COSV53165719; called by muse, mutect2, varscan2
- RPH3A | c.780C>T p.S260= (on ENST00000389385 / NM_001143854.2; = p.S256= on NM_014954.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 6/27 reads (22%) | catalogued as COSV66993368; called by muse, mutect2, varscan2
- SENP5 | c.2043G>A p.L681= | Silent (SNP) | VAF 10/54 reads (19%) | catalogued as COSV60210938; called by muse, mutect2, varscan2
- SIPA1L1 | c.4452G>C p.L1484= | Silent (SNP) | VAF 12/168 reads (7%) | catalogued as COSV62174376; called by muse, mutect2
- SLC18A3 | c.1026C>G p.V342= | Silent (SNP) | VAF 20/58 reads (34%) | catalogued as COSV60334974; called by muse, varscan2
- SPEF2 | c.528G>A p.E176= | Silent (SNP) | VAF 7/27 reads (26%) | catalogued as COSV56798262, COSV56801282; called by muse, mutect2, varscan2
- ST8SIA6 | c.975G>A p.L325= | Silent (SNP) | VAF 49/125 reads (39%) | catalogued as COSV66472328; called by muse, mutect2, varscan2
- TECTA | c.4569C>T p.I1523= | Silent (SNP) | VAF 13/56 reads (23%) | catalogued as COSV50832260; called by muse, mutect2, varscan2
- TMEM147 | c.243G>C p.L81= | Silent (SNP) | VAF 14/64 reads (22%) | catalogued as COSV52866063, COSV52870579, COSV99382657; called by muse, mutect2, varscan2
- TRO | c.4071C>T p.F1357= | Silent (SNP) | VAF 20/47 reads (43%) | catalogued as COSV51509044; called by muse, mutect2, varscan2
- TTN | c.708A>T p.T236= | Silent (SNP) | VAF 10/44 reads (23%) | catalogued as COSV60404237; called by muse, mutect2, varscan2
- UGT2B15 | c.1581G>A p.K527= | Silent (SNP) | VAF 21/111 reads (19%) | catalogued as COSV57737247; called by muse, mutect2, varscan2
- XIRP2 | c.6630G>A p.P2210= (on ENST00000628543; = p.P2385= on NM_152381.6) | Silent (SNP) | VAF 16/71 reads (23%) | catalogued as rs187679773, COSV54717205; called by muse, mutect2, varscan2
- ZFHX4 | c.6553C>A p.R2185= | Silent (SNP) | VAF 8/126 reads (6%) | catalogued as COSV51441550, COSV51500998; called by muse, mutect2
- ZNF33A | c.1809A>T p.T603= (on ENST00000458705 / NM_006974.3; = p.T604= on NM_006954.2) | Silent (SNP) | VAF 16/42 reads (38%) | catalogued as COSV56728364; called by muse, mutect2, varscan2
- ZNF559 | c.1392A>C p.P464= | Silent (SNP) | VAF 12/47 reads (26%) | catalogued as COSV57837880; called by muse, mutect2, varscan2
- C14orf177 | n.707A>G | RNA (SNP) | VAF 20/91 reads (22%) | catalogued as COSV57901990; called by muse, varscan2
- CCNQP1 | n.532G>C | RNA (SNP) | VAF 17/67 reads (25%) | called by muse, mutect2, varscan2
- HLA-F | chr6:29728094 T>C | 3'Flank (SNP) | VAF 8/26 reads (31%) | catalogued as rs1277150753; called by mutect2, varscan2
- KRT18P55 | n.1127G>A | RNA (SNP) | VAF 14/45 reads (31%) | catalogued as rs1391198349; called by muse, mutect2, varscan2
- SYNE1 | c.24977-1791G>T | Intron (SNP) | VAF 10/39 reads (26%) | catalogued as COSV99583887; called by muse, mutect2, varscan2
- TTN | c.10361-4452A>G | Intron (SNP) | VAF 5/31 reads (16%) | catalogued as rs777422156, COSV60404179; called by muse, mutect2
